Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8K8, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8K8-01A (Primary Tumor).

[page 1 of 4]
printed

UUID: 859216F2-7122-4F06-B65E-380D3F22F4ED TCGA-VD-ABK8-01A-PR		Redacted	Page 1 of 4
		REPORT Tel:	
Forename 	Sex 	Clinical Consultant & Location 	
Unit No 			

This Copy For:

SPECIMEN

Enucleated left eye

CLINICAL DETAILS

Suspected choroidal melanoma.

MACROSCOPIC DESCRIPTION

A left eye.

Dimensions: Axial 24mm, Horizontal 23mm, Vertical 23mm

Cornea: Horizontal 12mm, Vertical 12mm

Description: clear

Optic nerve

Length 12mm, Diameter 4mm

Anterior chamber: normal depth

On trans-illumination, a shadow located superiorly measuring 19 x 18mm.

Plane of section: vertical

Intraocular description:

On opening the eye a large pigmented choroidal melanoma measuring 16mm LBD x 12mm in height.

Tumour size

;BD 16mm, Height 12mm

MICROSCOPY

Histologically, the enucleated eye demonstrates a normal anterior segment with an unremarkable cornea, a deep anterior chamber and open angles. The iris leaves are unremarkable. The ciliary muscles are moderately atrophic and there is moderate hyalinisation of the ciliary processes. The lens shows advanced cataractous changes.

In the posterior third of the posterior segment, a choroidal

ICD-0-3
Melanoma, epithelioid & spindle cell mixed
Site D Choroid 069.3
9/11/14

Reported:

Pathologist:

Electronically Verified:

[page 2 of 4]
Department of Pathology

Page 2 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	[REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

melanoma can be seen. This is dome-shaped with a large accompanying exudative retinal detachment. The retina overlying the tumour is atrophic with degenerative changes.

The tumour is pigmented and consists of a mixture of cells, both epithelioid and spindle cells, with a dominance of the latter. The epithelioid cell component represents 15% of the tumour cell population. The melanoma cells are immunoreactive for MelanA and HSP-27 (score 2).

The number of mitoses is high approx. 12/40 high power fields.

The microvasculature of the melanoma is prominent, and closed loops are focally present. Occasional "vascular lakes" can be observed; in these tumour cells can be seen located within the lumen.

The lymphocytic infiltrate within tumour is minimal. Macrophages are scattered throughout the tumour in a moderately density. There is no evidence of scleral invasion or of extraocular growth. The optic nerve is tumour free, and demonstrates mild atrophic changes. The examined vortex veins are free of tumour.

DIAGNOSIS

Choroid melanoma of mixed cell type.

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	2= Closed loops
NECROSIS	No

Reported

Pathologist:

Electronically Verified:

[page 3 of 4]
Department of Pathology

Page 3 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	[REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	12 /40 HPF
DIFFUSE MELANOMA	No

SPREAD	1= No
--------	-------

CLEARANCE	2= Adequate
-----------	-------------

HSP-27 POSITIVITY	2= 21-70%
-------------------	-----------

LARGE DIAMETER	16 mm
THICKNESS	12 mm

COMMENTS:

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow as soon as these investigations are complete.

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report.

Reported:

Pathologist:

Electronically Verified:

[page 4 of 4]
Department of Pathology

Page 4 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

In summary, sequence analysis demonstrated: normal chromosome 1, monosomy 3, normal chromosome 6 and gains in chromosome 8.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist:

Electronically Verified:

Diagnostic Discrepancy		

Source: NCI Genomic Data Commons file 3eaefd23-1abc-4ff3-af1e-a952b3dcac6c (TCGA-VD-A8K8.859216F2-7122-4F06-B65E-380D3F22F4ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).